Somatic mutation profile of tumor specimen 0DNRUX from CCDI case PBCBXP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,591 days).
Specimen 0DNRUX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed188cab-ba39-4493-9c25-58fdc9c7846e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNRTS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4223f08c-083f-4fe5-92d1-d22d340e4e9c

The open-access MAF lists 38 somatic variants for this specimen: 34 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 3, Frame Shift Ins 2, Splice Region 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.5455G>A p.D1819N (on ENST00000333535 / NM_198056.3; = p.D1818N on NM_000335.5) | Missense Mutation (SNP) | VAF 303/710 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs137854619, CM064254; ClinVar: likely benign / uncertain significance / pathogenic / not provided / benign; called by muse, varscan2
- ABCC6 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 120/979 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs773079563, COSV52741597; called by muse, varscan2
- AHNAK | c.8739A>C p.E2913D | Missense Mutation (SNP) | VAF 166/1230 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99949128; called by muse, varscan2
- ARHGAP25 | c.971C>T p.S324L (on ENST00000409202 / NM_001007231.3; = p.S316L on NM_014882.3) | Missense Mutation (SNP) | VAF 108/516 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs766951301; called by muse, varscan2
- BMPR2 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 105/422 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as CM035591; called by muse, varscan2
- CUBN | c.5951C>T p.T1984M | Missense Mutation (SNP) | VAF 75/568 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs150924438; called by muse, varscan2
- DDX3X | c.1619C>T p.A540V (on ENST00000399959; = p.A541V on NM_001356.5) | Missense Mutation (SNP) | VAF 230/237 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67863520, COSV67864045; called by muse, varscan2
- DNER | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 124/616 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs765060539, COSV100518737; called by muse, varscan2
- ERICH6 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 142/1118 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs200586444, COSV104405552; called by muse, varscan2
- LAT | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 159/1122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs372595985; called by muse, varscan2
- LILRB3 | c.1487G>A p.R496H (on ENST00000346401; = p.R484H on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/603 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs752813012; called by muse, varscan2
- MED12 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 160/388 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199469667, COSV61329305, COSV61331528; ClinVar: not provided; called by muse, varscan2
- PLVAP | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 116/750 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771233221; called by muse, varscan2
- PRDM1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 136/1008 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.154); catalogued as rs550094148; called by muse, varscan2
- RNF152 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 86/628 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); catalogued as rs1293060457; called by muse, varscan2
- ROBO3 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 265/692 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199762736, COSV67303090; called by muse, varscan2
- ZNF107 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 104/728 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV61329400; called by muse, varscan2
- ZNF516 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs201679855; called by muse, varscan2
- AL162231.1 | c.108-8C>T | Splice Region (SNP) | VAF 62/486 reads (13%) | called by muse, varscan2
- ANO6 | c.1163G>A p.W388* | Nonsense Mutation (SNP) | VAF 47/302 reads (16%) | called by muse, varscan2
- ARFGEF3 | c.2668G>T p.G890W | Missense Mutation (SNP) | VAF 106/621 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- BMPR2 | c.1651T>G p.Y551D | Missense Mutation (SNP) | VAF 169/686 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, varscan2
- DDX60L | c.4012A>T p.S1338C | Missense Mutation (SNP) | VAF 162/992 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, varscan2
- GUCY1A2 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 112/722 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.329); called by muse, varscan2
- LEMD1 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 185/421 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- MAGEB3 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MMP16 | c.1705A>G p.I569V | Missense Mutation (SNP) | VAF 92/810 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.08); called by muse, varscan2
- NAP1L5 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 102/720 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.26); called by muse, varscan2
- OR5D18 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 108/692 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, varscan2
- PRDM8 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 240/1249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- RBM26 | c.2444T>C p.L815P (on ENST00000438737 / NM_001366735.2; = p.L788P on NM_022118.5) | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- SETD1B | c.1651C>A p.Q551K | Missense Mutation (SNP) | VAF 164/768 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); called by muse, varscan2
- UBN2 | c.1254_1257dup p.P420* | Frame Shift Ins (INS) | VAF 76/676 reads (11%) | called by pindel, varscan2
- WDR3 | c.1752dup p.L585Sfs*18 | Frame Shift Ins (INS) | VAF 40/392 reads (10%) | called by pindel, varscan2
- IRF6 | c.1261C>T p.L421= | Silent (SNP) | VAF 74/582 reads (13%) | called by muse, varscan2
- S100A10 | c.21C>T p.H7= | Silent (SNP) | VAF 128/949 reads (13%) | catalogued as rs148864594; called by muse, varscan2
- SLC4A8 | c.3123C>A p.P1041= | Silent (SNP) | VAF 73/382 reads (19%) | called by muse, varscan2
- RPL13 | c.105-9C>T | Intron (SNP) | VAF 64/552 reads (12%) | catalogued as rs969244368; called by muse, varscan2
